Somatic mutation profile of tumor specimen TCGA-46-3769-01A (aliquot TCGA-46-3769-01A-01D-0983-08) from TCGA case TCGA-46-3769, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; Age at diagnosis: 57.3 years (20,941 days).
Specimen TCGA-46-3769-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82aca012-f0b1-46a6-919c-f4f5039c7703.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-46-3769-10A (Blood Derived Normal), aliquot TCGA-46-3769-10A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53714755-fdb7-411e-b13f-d4a490ee0b83

The open-access MAF lists 1,017 somatic variants for this specimen: 730 protein-altering or splice-affecting, 264 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 618, Silent 264, Nonsense Mutation 65, Splice Site 21, Frame Shift Del 15, Intron 9, RNA 8, Splice Region 4, Frame Shift Ins 3, In Frame Del 2, 3'UTR 2, 5'Flank 2.

Variants (750 of 1,017; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.1709G>A p.R570Q (on ENST00000372530 / NM_001198934.2; = p.R527Q on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/91 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745844891, COSV55085418; called by muse, mutect2, varscan2
- HADHA | c.1221-1G>C p.X407_splice | Splice Site (SNP) | VAF 10/44 reads (23%) | catalogued as rs1057516233, COSV66107269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1760G>A p.R587Q (on ENST00000373993 / NM_138932.2; = p.R579Q on NM_014576.4) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.968); catalogued as rs530902814, COSV50965034; called by muse, mutect2, varscan2
- AASS | c.2095G>T p.G699C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV62789965; called by muse, mutect2, varscan2
- ABCA1 | c.3762G>C p.E1254D | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66066189; called by mutect2, varscan2
- ABCA13 | c.5209A>G p.K1737E | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as rs1291336531, COSV70028484; called by muse, mutect2, varscan2
- ABCA4 | c.3810A>T p.E1270D | Missense Mutation (SNP) | VAF 78/170 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV64673437; called by muse, mutect2, varscan2
- ABCA7 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV54029228; called by mutect2, varscan2
- ABCA8 | c.3811T>C p.F1271L | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.228); catalogued as COSV52200972; called by muse, varscan2
- ABCA9 | c.1208T>A p.L403H | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.053); catalogued as COSV60624690; called by muse, mutect2, varscan2
- ABCB11 | c.2191C>A p.P731T | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs201240844, CM129434, COSV55590267; called by muse, mutect2, varscan2
- ABCB4 | c.25G>C p.G9R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV55935244, COSV55940391; called by muse, mutect2, varscan2
- ABCC9 | c.4614T>G p.N1538K | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV53971036; called by muse, mutect2
- ABCF2 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV55182965; called by muse, mutect2, varscan2
- ABCF3 | c.1391+1G>A p.X464_splice | Splice Site (SNP) | VAF 14/52 reads (27%) | catalogued as COSV53052534; called by muse, mutect2, varscan2
- ABLIM3 | c.1681G>C p.E561Q | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.099); catalogued as COSV58643186; called by muse, mutect2, varscan2
- AC136428.1 | c.100G>T p.G34W | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV71169137, COSV71169153, COSV71169248; called by muse, mutect2, varscan2
- ACOT8 | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as rs1225726015, COSV54169414; called by muse, mutect2, varscan2
- ACTL7A | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs369003397, COSV61776698; called by muse, mutect2, varscan2
- ACTN2 | c.1489A>G p.T497A | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.968); catalogued as COSV63974892; called by muse, mutect2, varscan2
- ACTRT2 | c.384C>G p.F128L | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV65759325; called by muse, mutect2, varscan2
- ACTRT3 | c.899C>G p.S300* | Nonsense Mutation (SNP) | VAF 32/178 reads (18%) | catalogued as COSV57754358; called by muse, mutect2, varscan2
- ADAMTS16 | c.515G>T p.R172L | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56987073, COSV56989155; called by muse, mutect2, varscan2
- ADAMTS9 | c.4696G>A p.E1566K | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as COSV55780865; called by muse, mutect2, varscan2
- ADCK1 | c.1258C>A p.L420I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.55); catalogued as COSV53080982, COSV99451409; called by muse, mutect2, varscan2
- ADCY2 | c.1501T>A p.W501R | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV57871855; called by muse, mutect2, varscan2
- ADCY2 | c.3188T>A p.I1063N | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57871867; called by muse, mutect2, varscan2
- ADCY3 | c.1391T>A p.L464Q | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53167430; called by muse, mutect2, varscan2
- ADCY6 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs747242622, COSV57167802; called by muse, mutect2, varscan2
- ADGRB1 | c.2458G>A p.D820N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs368988728; called by muse, mutect2, varscan2
- ADGRG2 | c.1808G>C p.C603S (on ENST00000379869 / NM_001079858.3; = p.C600S on NM_005756.4) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61339069; called by muse, mutect2, varscan2
- ADGRV1 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1009316043, COSV101315794, COSV67984947; called by muse, mutect2, varscan2
- AGBL1 | c.280A>C p.K94Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69799144; called by muse, mutect2, varscan2
- AGBL5 | c.2636C>A p.P879Q | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); catalogued as COSV100789510; called by mutect2, varscan2
- AHNAK2 | c.11381A>G p.K3794R | Missense Mutation (SNP) | VAF 110/303 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.577); catalogued as COSV60915065; called by muse, mutect2, varscan2
- AHNAK2 | c.7220C>G p.P2407R | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60915072; called by muse, mutect2, varscan2
- ALB | c.508C>T p.H170Y | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as COSV55738061; called by muse, mutect2, varscan2
- ALCAM | c.530T>A p.L177Q | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV60248160; called by muse, mutect2, varscan2
- ALPK1 | c.747G>C p.M249I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51584922; called by muse, mutect2, varscan2
- AMPD2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV56650590; called by muse, mutect2
- AMPH | c.415A>T p.S139C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57741590; called by muse, mutect2, varscan2
- ANGEL1 | c.1927G>T p.A643S | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.101); catalogued as COSV51873246; called by muse, mutect2, varscan2
- ANK2 | c.10714A>T p.R3572W | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52160530; called by muse, mutect2, varscan2
- ANKRD50 | c.665A>G p.H222R | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as rs749428839, COSV72385535; called by muse, mutect2, varscan2
- ANO1 | c.722del p.F241Sfs*14 | Frame Shift Del (DEL) | VAF 12/113 reads (11%) | catalogued as COSV60282537; called by mutect2, pindel
- ANTXR1 | c.1204G>T p.G402C | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58013442; called by muse, mutect2, varscan2
- AP002512.3 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV54406614; called by muse, mutect2, varscan2
- APOA4 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as rs1260305940, COSV63360426, COSV63360448; called by muse, mutect2, varscan2
- APOB | c.5410A>G p.N1804D | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV51934906; called by muse, mutect2, varscan2
- APP | c.924C>G p.Y308* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as COSV60998327; called by muse, mutect2, varscan2
- APPL2 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV51588562, COSV51590279; called by muse, mutect2, varscan2
- ARHGAP11A | c.2128G>C p.D710H | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV55705886, COSV55706251; called by muse, mutect2, varscan2
- ARHGAP17 | c.1442G>T p.R481L | Missense Mutation (SNP) | VAF 55/90 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51507114; called by muse, mutect2, varscan2
- ARHGAP19 | c.1021C>T p.H341Y | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV57392874; called by muse, mutect2, varscan2
- ARHGAP20 | c.1411C>G p.Q471E | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as rs1207839599, COSV52810921; called by muse, mutect2, varscan2
- ARHGAP21 | c.4387G>A p.E1463K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV57605700, COSV99080426; called by muse, mutect2, varscan2
- ARHGAP25 | c.1149G>T p.W383C (on ENST00000409202 / NM_001007231.3; = p.W375C on NM_014882.3) | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54902197; called by muse, mutect2, varscan2
- ARHGEF17 | c.601C>A p.Q201K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.011); catalogued as COSV55232410; called by muse, mutect2, varscan2
- ASPRV1 | c.1001C>G p.S334* | Nonsense Mutation (SNP) | VAF 18/126 reads (14%) | catalogued as COSV57228075; called by muse, mutect2, varscan2
- ATF7IP | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 33/57 reads (58%) | catalogued as COSV53770608; called by muse, mutect2, varscan2
- ATRX | c.1822G>T p.V608F | Missense Mutation (SNP) | VAF 77/161 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.368); catalogued as COSV64876363; called by muse, mutect2, varscan2
- B3GNT3 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs370538223; called by muse, mutect2, varscan2
- BCL9 | c.359C>G p.S120C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as rs1553203031, COSV52341980, COSV52344132; called by muse, mutect2, varscan2
- BDH1 | c.639C>A p.F213L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as COSV64018475, COSV64019757; called by muse, mutect2, varscan2
- BDNF | c.48G>A p.M16I | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.643); catalogued as COSV59235153; called by muse, mutect2, varscan2
- BDP1 | c.6034A>T p.I2012L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV62431294; called by muse, mutect2, varscan2
- BOD1L1 | c.5978A>T p.K1993I | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV50012835; called by muse, mutect2, varscan2
- BPIFA3 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV64925841; called by muse, mutect2
- BPIFB1 | c.23C>G p.T8S | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV53606563; called by muse, mutect2, varscan2
- BPIFB2 | c.1026G>T p.E342D | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.214); catalogued as COSV50064564, COSV99401062; called by muse, mutect2, varscan2
- BPIFB4 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs143050216; called by muse, mutect2, varscan2
- BRCA1 | c.3478A>T p.K1160* | Nonsense Mutation (SNP) | VAF 10/100 reads (10%) | catalogued as COSV58789669; called by mutect2, varscan2
- BSN | c.5806C>A p.Q1936K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99607934; called by muse, mutect2, varscan2
- BTN2A2 | c.1543C>T p.H515Y | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV61857363; called by muse, mutect2, varscan2
- BTN3A3 | c.415G>T p.V139L | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV55071915; called by muse, mutect2, varscan2
- BTNL3 | c.71C>A p.P24Q | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs777131989, COSV61564855, COSV61564999; called by muse, mutect2, varscan2
- C10orf90 | c.1637C>A p.P546H | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV52954997; called by muse, mutect2
- C3AR1 | c.511A>T p.R171* | Nonsense Mutation (SNP) | VAF 27/120 reads (23%) | catalogued as COSV50818723; called by muse, mutect2, varscan2
- C3orf22 | c.403G>T p.G135W | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV100559521; called by muse, mutect2, varscan2
- C7orf25 | c.402G>T p.R134S | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.604); catalogued as COSV63273657, COSV63274313; called by muse, mutect2, varscan2
- CACNA1C | c.2313G>T p.E771D | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as rs796972533, COSV59717014; called by muse, mutect2, varscan2
- CACNA1C | c.2593C>T p.L865F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); catalogued as COSV59705769, COSV59717018; called by mutect2, varscan2
- CADPS2 | c.2004G>T p.W668C | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV57362858; called by muse, mutect2, varscan2
- CAPN13 | c.371G>C p.G124A | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54430479, COSV99700676; called by muse, mutect2, varscan2
- CARMIL1 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV61513411; called by muse, mutect2, varscan2
- CASK | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as COSV59366374; called by muse, mutect2, varscan2
- CASS4 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as COSV64386420, COSV64386735, COSV64386803; called by muse, mutect2, varscan2
- CCDC105 | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1382254436, COSV52963911; called by muse, mutect2, varscan2
- CCDC172 | c.438G>C p.M146I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60937716; called by muse, mutect2, varscan2
- CCDC33 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV58349324; called by muse, mutect2, varscan2
- CCDC39 | c.561G>C p.Q187H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV56483854; called by muse, mutect2, varscan2
- CCDC51 | c.1067C>A p.A356D | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.232); catalogued as COSV56489521; called by muse, mutect2, varscan2
- CCDC73 | c.1892C>G p.S631W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV58798365; called by muse, mutect2, varscan2
- CCDC96 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV100027881; called by muse, mutect2, varscan2
- CCM2L | c.113C>A p.P38H | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1482524462, COSV52950248; called by muse, mutect2, varscan2
- CD4 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 52/75 reads (69%) | catalogued as COSV50590632; called by muse, mutect2, varscan2
- CD6 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV57838090; called by muse, mutect2, varscan2
- CDH12 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66404477; called by muse, mutect2, varscan2
- CDH23 | c.4691C>G p.S1564C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.94); catalogued as rs778724450, COSV56462916; called by muse, mutect2, varscan2
- CDH4 | c.1986G>T p.W662C | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64654111; called by muse, mutect2, varscan2
- CDH8 | c.2095G>T p.D699Y | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54866417, COSV54867931; called by muse, mutect2, varscan2
- CEBPA | c.1076G>C p.*359Sext*36 | Nonstop Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as COSV57197346, COSV57197664; called by muse, mutect2, varscan2
- CELF6 | c.517A>T p.S173C | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99763683; called by muse, mutect2, varscan2
- CENPE | c.6718G>T p.E2240* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV54380959; called by muse, mutect2
- CENPF | c.1446+1G>T p.X482_splice | Splice Site (SNP) | VAF 10/30 reads (33%) | catalogued as COSV65274878; called by muse, mutect2, varscan2
- CENPF | c.4600G>T p.E1534* | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | catalogued as COSV65274884; called by muse, mutect2, varscan2
- CENPJ | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.154); catalogued as COSV67883424; called by muse, mutect2, varscan2
- CEP126 | c.2450A>C p.Q817P | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV54825112; called by muse, mutect2, varscan2
- CEP170 | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0.012); catalogued as COSV60508915; called by muse, mutect2, varscan2
- CEP63 | c.1337G>C p.R446T | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV59676245; called by muse, mutect2, varscan2
- CFAP206 | c.1421C>A p.A474D | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51534114; called by muse, mutect2, varscan2
- CFAP47 | c.5000C>G p.S1667C | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as COSV100544747, COSV57973783; called by muse, mutect2, varscan2
- CFAP61 | c.1522C>A p.L508M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV55628881; called by muse, mutect2, varscan2
- CHD5 | c.5432A>G p.Y1811C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV52414151; called by muse, mutect2
- CHIC2 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55755100; called by muse, varscan2
- CLDN19 | c.294C>G p.S98R | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56417934; called by mutect2, varscan2
- CLDN5 | c.232C>A p.Q78K (on ENST00000618236 / NM_001363066.2; = p.Q163K on NM_003277.4) | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV54245275; called by muse, varscan2
- CLSTN2 | c.690G>C p.E230D | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs1459767403, COSV71719867, COSV71720796; called by muse, mutect2, varscan2
- CMKLR1 | c.957G>T p.M319I (on ENST00000312143 / NM_001142344.2; = p.M317I on NM_004072.3) | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as COSV56438182; called by muse, mutect2, varscan2
- CNGA2 | c.243C>A p.N81K | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs144004735, COSV61704469; called by muse, varscan2
- CNGA4 | c.478C>A p.R160S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV101171784; called by muse, mutect2, varscan2
- CNOT1 | c.6750C>G p.I2250M | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55316518, COSV99800565; called by muse, mutect2, varscan2
- CNOT4 | c.1676G>T p.G559V (on ENST00000541284 / NM_001190850.1; = p.G556V on NM_001190849.2) | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64157659; called by muse, mutect2
- CNTN1 | c.755A>T p.Y252F | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as COSV61639528, COSV61645691; called by muse, mutect2, varscan2
- CNTNAP5 | c.363A>T p.K121N | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV70478704; called by muse, mutect2, varscan2
- CNTNAP5 | c.1331A>C p.N444T | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV70485447; called by muse, mutect2, varscan2
- COCH | c.1112C>A p.P371H (on ENST00000216361 / NM_001347720.1; = p.P306H on NM_004086.3) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV99363530; called by muse, mutect2, varscan2
- COL11A1 | c.4678G>T p.G1560C | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as COSV62183350, COSV62184151; called by muse, mutect2, varscan2
- COL11A1 | c.3013G>A p.E1005K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100615333, COSV62183357; called by muse, mutect2, varscan2
- COL11A1 | c.2470G>T p.D824Y | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV62183364; called by muse, mutect2, varscan2
- COL12A1 | c.4306G>A p.E1436K | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.043); catalogued as COSV59395775; called by muse, mutect2, varscan2
- COL19A1 | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV59572612, COSV59577478; called by muse, mutect2, varscan2
- COL24A1 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.612); catalogued as rs1039833988, COSV65306067; called by muse, mutect2, varscan2
- COL5A3 | c.4776T>A p.F1592L | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT tolerated (0.65); PolyPhen benign (0.444); catalogued as COSV53410473; called by muse, mutect2, varscan2
- COL6A5 | c.7176G>A p.W2392* (on ENST00000312481; = p.W2388* on NM_153264.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/78 reads (12%) | catalogued as COSV55201261; called by muse, varscan2
- COQ8B | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54574752; called by muse, mutect2, varscan2
- CPA6 | c.326T>C p.I109T | Missense Mutation (SNP) | VAF 62/109 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs151119622; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD2 | c.4721T>A p.L1574Q | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV53911051; called by muse, mutect2, varscan2
- CSMD2 | c.2428G>T p.D810Y | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53911075, COSV53950617; called by muse, mutect2, varscan2
- CSMD3 | c.3848C>G p.A1283G (on ENST00000297405 / NM_001363185.1; = p.A1179G on NM_052900.3) | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as rs1289460487, COSV52176973, COSV99820986; called by muse, mutect2, varscan2
- CSMD3 | c.3261T>A p.Y1087* (on ENST00000297405 / NM_001363185.1; = p.Y983* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as COSV99830539; called by muse, mutect2
- CTBP1 | c.935G>T p.C312F | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV52073999; called by muse, mutect2, varscan2
- CTCFL | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 82/216 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as COSV54774119; called by muse, mutect2, varscan2
- CTPS1 | c.1449G>T p.E483D | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV65452425; called by muse, mutect2, varscan2
- CUBN | c.5656G>T p.A1886S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV64715416; called by muse, mutect2, varscan2
- CX3CR1 | c.929A>T p.K310I | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV64193883; called by muse, mutect2, varscan2
- CYLC2 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.199); catalogued as COSV66337494, COSV66340061; called by muse, mutect2, varscan2
- CYP4B1 | c.1316A>G p.H439R | Missense Mutation (SNP) | VAF 47/80 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54723448; called by muse, mutect2, varscan2
- CYP7A1 | c.498G>T p.W166C | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1354168442, COSV56963482; called by muse, mutect2, varscan2
- DCDC1 | c.2123G>T p.G708V | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60842176; called by muse, mutect2, varscan2
- DDB2 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.231); catalogued as COSV57038587; called by muse, mutect2, varscan2
- DDHD1 | c.1947G>T p.L649F (on ENST00000323669; = p.L846F on NM_030637.3) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.177); catalogued as COSV60359201; called by muse, mutect2, varscan2
- DDX60L | c.2695G>C p.A899P | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1174062959; called by muse, mutect2, varscan2
- DEFA5 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 22/46 reads (48%) | catalogued as COSV57962114; called by muse, varscan2
- DEFB110 | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 40/105 reads (38%) | catalogued as rs1333243392, COSV64484490, COSV64484561; called by muse, mutect2, varscan2
- DENND2B | c.1713G>T p.K571N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.937); catalogued as COSV58203540; called by mutect2, varscan2
- DGAT2L6 | c.667T>A p.Y223N | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60717730; called by muse, mutect2, varscan2
- DHX57 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 6/51 reads (12%) | catalogued as COSV54885241; called by mutect2, varscan2
- DLGAP3 | c.1244C>G p.T415R | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.1); catalogued as COSV52393906; called by muse, mutect2, varscan2
- DLST | c.903G>A p.V301= | Splice Region (SNP) | VAF 6/56 reads (11%) | catalogued as COSV53166223, COSV99471825; called by muse, mutect2, varscan2
- DNAH10 | c.3803G>T p.G1268V (on ENST00000409039; = p.G1207V on NM_207437.3) | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV68993579; called by muse, mutect2, varscan2
- DNAH11 | c.2857C>T p.P953S | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.139); catalogued as COSV60955253; called by muse, mutect2, varscan2
- DNAI4 | c.38C>G p.A13G | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.034); catalogued as COSV63084337, COSV63085458; called by muse, mutect2, varscan2
- DNAJB5 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV56624619; called by muse, mutect2, varscan2
- DNMBP | c.3049C>T p.Q1017* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV60624951; called by muse, mutect2, varscan2
- DOCK1 | c.3904G>A p.E1302K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs753464561, COSV54739402; called by mutect2, varscan2
- DOCK2 | c.791G>T p.R264L | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV56952192, COSV56957547; called by muse, mutect2, varscan2
- DOCK2 | c.5109G>C p.K1703N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.991); catalogued as COSV56957556; called by muse, mutect2, varscan2
- DPP6 | c.1067T>A p.L356Q (on ENST00000377770 / NM_001364500.2; = p.L294Q on NM_001936.5) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59612342; called by muse, mutect2, varscan2
- DPYSL5 | c.1603C>A p.L535I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.677); catalogued as COSV56511807; called by muse, mutect2, varscan2
- DRGX | c.587A>C p.Y196S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.991); catalogued as COSV65136247; called by muse, mutect2, varscan2
- DSG2 | c.180G>C p.E60D | Missense Mutation (SNP) | VAF 73/130 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55199095; called by muse, mutect2, varscan2
- DUSP10 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV60457579; called by muse, mutect2, varscan2
- DUSP10 | c.187T>A p.S63T | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV60457581; called by muse, mutect2, varscan2
- DYSF | c.3909G>T p.E1303D | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50321128; called by muse, mutect2, varscan2
- EEF2K | c.393C>G p.I131M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV53781686; called by muse, mutect2, varscan2
- EFCAB7 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV64314502; called by muse, mutect2, varscan2
- EFHD1 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV51132580; called by muse, mutect2, varscan2
- EFNB1 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52661677; called by muse, mutect2, varscan2
- EGFR | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.488); catalogued as rs751570775, COSV51799159; called by muse, mutect2
- EGLN3 | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV51654689; called by muse, mutect2, varscan2
- EIF4G1 | c.2042G>A p.R681H (on ENST00000346169 / NM_198241.3; = p.R485H on NM_004953.5) | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs750028797, COSV59990880; called by muse, mutect2, varscan2
- EIF4G1 | c.2668A>G p.I890V (on ENST00000346169 / NM_198241.3; = p.I695V on NM_004953.5) | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs373331022; called by muse, mutect2, varscan2
- ELAVL4 | c.289C>G p.P97A | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV63915776; called by muse, mutect2, varscan2
- ELMO2 | c.435G>C p.E145D | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as COSV51682899; called by muse, mutect2, varscan2
- ELOVL5 | c.749A>T p.Y250F | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58650436; called by muse, mutect2
- ELOVL5 | c.32A>G p.Y11C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1355897667, COSV58650458; called by muse, mutect2, varscan2
- ELP2 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 46/362 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60850958; called by muse, mutect2, varscan2
- EMSY | c.163G>C p.V55L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.042); catalogued as rs1306011443, COSV58260178; called by muse, mutect2
- ENDOD1 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as rs771483722, COSV53589489; called by muse, mutect2, varscan2
- ENPP7 | c.1320G>C p.R440S | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.005); catalogued as COSV60386477; called by muse, varscan2
- EPHA7 | c.2530G>C p.D844H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65182470; called by muse, mutect2, varscan2
- EPHB3 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs201322151, COSV57805865; called by muse, mutect2, varscan2
- EPRS1 | c.3788G>T p.G1263V | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV65098839; called by muse, mutect2, varscan2
- F13A1 | c.1308C>A p.V436= | Splice Region (SNP) | VAF 8/25 reads (32%) | catalogued as COSV53558305; called by mutect2, varscan2
- FAM166A | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61116624; called by muse, mutect2, varscan2
- FAM214B | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as COSV59716154; called by muse, mutect2
- FAT1 | c.4648G>A p.V1550I | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.058); catalogued as rs1358786582, COSV71673811; called by muse, mutect2, varscan2
- FAT3 | c.11753A>T p.H3918L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53108589; called by muse, mutect2, varscan2
- FAT4 | c.14497G>C p.D4833H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV58684318; called by muse, mutect2, varscan2
- FBN2 | c.3104C>A p.T1035N | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.062); catalogued as COSV52512431; called by muse, mutect2, varscan2
- FBN3 | c.4168G>C p.E1390Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV54460252; called by muse, mutect2, varscan2
- FBXO40 | c.476C>A p.T159N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.023); catalogued as COSV57523961; called by muse, mutect2, varscan2
- FER1L6 | c.2687C>A p.P896H | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67549803, COSV67551394; called by muse, mutect2, varscan2
- FLNA | c.6019G>A p.V2007M (on ENST00000369850 / NM_001110556.2; = p.V1999M on NM_001456.3) | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.483); catalogued as rs200956777, COSV61042743; called by muse, mutect2, varscan2
- FLT1 | c.1241T>C p.V414A | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV56727479; called by muse, mutect2, varscan2
- FNDC1 | c.5364G>T p.K1788N | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51937592; called by muse, mutect2, varscan2
- FOLH1 | c.1684G>C p.V562L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV99923004; called by muse, mutect2, varscan2
- FOXO4 | c.934C>G p.L312V | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV58575249; called by muse, mutect2, varscan2
- FPGT | c.1476G>C p.K492N | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV63839657; called by muse, mutect2
- FRAS1 | c.5044G>C p.D1682H | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53609455; called by muse, mutect2, varscan2
- FREM1 | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66523279; called by muse, mutect2, varscan2
- FREM2 | c.3475G>T p.V1159L | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.166); catalogued as COSV54837335; called by muse, mutect2, varscan2
- FREM2 | c.5125C>G p.L1709V | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.596); catalogued as COSV54837351; called by muse, mutect2, varscan2
- FRMPD3 | c.1831G>C p.D611H | Missense Mutation (SNP) | VAF 63/100 reads (63%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.212); catalogued as COSV99346070; called by muse, mutect2, varscan2
- FXR1 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV59762906; called by muse, mutect2, varscan2
- FYB2 | c.1262A>T p.Q421L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV100599111, COSV58584993; called by muse, mutect2, varscan2
- FZD3 | c.548G>T p.R183L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.201); catalogued as COSV53535421, COSV53535846; called by muse, mutect2, varscan2
- G3BP2 | c.1253G>C p.R418T | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV62976342; called by muse, mutect2, varscan2
- GAB1 | c.2038G>T p.G680W | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53756562; called by muse, mutect2, varscan2
- GAB4 | c.1124C>A p.A375E | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); catalogued as COSV68753818; called by muse, mutect2, varscan2
- GABBR1 | c.1711G>T p.G571W | Missense Mutation (SNP) | VAF 39/60 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV63542462; called by muse, mutect2, varscan2
- GABRA1 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV50103894; called by muse, mutect2, varscan2
- GABRD | c.938A>T p.Y313F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66080554; called by muse, mutect2, varscan2
- GABRQ | c.1757C>A p.P586H | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV64781938; called by muse, mutect2, varscan2
- GALNT17 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61161763, COSV61165128; called by muse, mutect2, varscan2
- GALNTL6 | c.163G>T p.G55W | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as rs766849976, COSV72490895; called by muse, mutect2, varscan2
- GBP4 | c.1298C>T p.T433I | Missense Mutation (SNP) | VAF 97/303 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs745623781, COSV63254254; called by muse, mutect2, varscan2
- GFRAL | c.35G>T p.S12I | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV61230851; called by muse, mutect2, varscan2
- GIMAP1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 97/210 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs867001533, COSV56188051; called by muse, mutect2, varscan2
- GJA10 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs896103911, COSV101005484, COSV65355193; called by muse, mutect2, varscan2
- GLI3 | c.1465A>T p.R489W | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV67888383; called by muse, mutect2, varscan2
- GLI4 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60681973; called by muse, mutect2, varscan2
- GNAI1 | c.905A>G p.Y302C | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV63522894; called by muse, mutect2
- GNB4 | c.494C>T p.T165I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51709546; called by muse, mutect2, varscan2
- GNPDA2 | c.536C>G p.S179* | Nonsense Mutation (SNP) | VAF 16/94 reads (17%) | catalogued as rs757950405, COSV54946698; called by muse, mutect2, varscan2
- GOLGB1 | c.438A>G p.I146M | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV61465681; called by muse, mutect2, varscan2
- GP2 | c.1040G>A p.G347E (on ENST00000381362 / NM_001007240.3; = p.G344E on NM_001502.4) | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56894019; called by muse, mutect2, varscan2
- GPC3 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 62/87 reads (71%) | catalogued as COSV63664007; called by muse, mutect2, varscan2
- GPD1 | c.101C>A p.P34Q | Missense Mutation (SNP) | VAF 80/161 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.286); catalogued as COSV56547980; called by muse, mutect2, varscan2
- GPR26 | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); catalogued as COSV52933892; called by muse, mutect2, varscan2
- GPR50 | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 66/109 reads (61%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763647516, COSV54439002, COSV54442660; called by muse, mutect2, varscan2
- GPR75 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61827149; called by muse, mutect2, varscan2
- GRIK3 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV66139716; called by muse, mutect2, varscan2
- GRIN2B | c.1285T>A p.C429S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV74205876; called by muse, mutect2, varscan2
- GRK7 | c.1261G>C p.E421Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.856); catalogued as COSV53822865; called by muse, mutect2, varscan2
- GRM1 | c.2650G>C p.G884R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV51144209; called by muse, mutect2
- GTF2A1 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV53337101; called by muse, mutect2, varscan2
- GTF3C2 | c.1790C>G p.S597C | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV53126541; called by muse, mutect2, varscan2
- H1-3 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 45/111 reads (41%) | catalogued as rs1208487692, COSV55096949; called by muse, mutect2, varscan2
- H1-5 | c.506A>T p.K169M | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58899981; called by muse, mutect2, varscan2
- H3C4 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.167); catalogued as COSV61911912; called by muse, mutect2, varscan2
- HAAO | c.558G>C p.W186C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99685325; called by mutect2, varscan2
- HAS2 | c.154T>A p.F52I | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV58263890, COSV58264040; called by muse, mutect2, varscan2
- HAUS5 | c.1214A>G p.K405R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52546571; called by muse, mutect2, varscan2
- HCN1 | c.1496G>T p.G499V | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV57508108; called by muse, mutect2, varscan2
- HCN1 | c.1495G>C p.G499R | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV57509885, COSV57512163; called by muse, mutect2, varscan2
- HEATR1 | c.1574G>T p.R525L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63980014, COSV63981077; called by mutect2, varscan2
- HEATR1 | c.1573C>T p.R525* | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | catalogued as COSV63981080; called by muse, mutect2, varscan2
- HECTD3 | c.2468G>A p.C823Y | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64670156; called by muse, mutect2, varscan2
- HEPACAM | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.364); catalogued as COSV53430078; called by muse, mutect2, varscan2
- HIVEP1 | c.6583G>A p.E2195K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV65101296; called by muse, mutect2, varscan2
- HJV | c.139G>C p.V47L | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.882); catalogued as COSV60951985; called by muse, mutect2
- HMCN1 | c.6304+2T>C p.X2102_splice | Splice Site (SNP) | VAF 13/77 reads (17%) | catalogued as COSV54899558; called by muse, mutect2, varscan2
- HMCN1 | c.13058G>T p.G4353V | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.642); catalogued as COSV54899570; called by muse, mutect2, varscan2
- HOXA3 | c.602C>G p.A201G | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57825122, COSV57826336; called by muse, mutect2, varscan2
- HOXB6 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 64/100 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV53313022; called by muse, mutect2, varscan2
- HOXD3 | c.430A>T p.K144* | Nonsense Mutation (SNP) | VAF 32/108 reads (30%) | catalogued as COSV50880514; called by muse, varscan2
- HSPB8 | c.419C>A p.T140K | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV56138059; called by muse, mutect2, varscan2
- ICA1 | c.1134G>C p.E378D | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.057); catalogued as COSV55578830; called by muse, mutect2, varscan2
- IFT172 | c.2398G>C p.E800Q | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.067); catalogued as COSV53133545; called by muse, mutect2, varscan2
- IFT88 | c.1930T>A p.F644I (on ENST00000319980 / NM_001318493.2; = p.F635I on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.355); catalogued as COSV60673230; called by muse, mutect2, varscan2
- IGHV3-13 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as rs1247407770; called by muse, mutect2, varscan2
- IGKV1D-43 | c.170G>A p.W57* | Nonsense Mutation (SNP) | VAF 25/228 reads (11%) | catalogued as rs750230100; called by muse, mutect2, varscan2
- IGKV2-30 | c.165C>A p.N55K | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs762103268; called by mutect2, varscan2
- IGSF10 | c.686G>A p.W229* | Nonsense Mutation (SNP) | VAF 17/90 reads (19%) | catalogued as rs764558798, COSV56785004; called by muse, mutect2, varscan2
- IL16 | c.1247T>A p.L416Q | Missense Mutation (SNP) | VAF 43/71 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV57263473; called by muse, mutect2, varscan2
- IL1RAPL1 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56260462; called by muse, mutect2, varscan2
- IL1RAPL2 | c.152T>A p.V51E | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV61156919; called by muse, mutect2, varscan2
- IL5RA | c.648C>A p.N216K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV56523146, COSV99842589; called by muse, mutect2, varscan2
- IMPDH1 | c.229G>T p.D77Y (on ENST00000470772 / NM_001142573.2; = p.D162Y on NM_000883.4) | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as COSV58316002; called by muse, mutect2, varscan2
- ING2 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV56564171; called by muse, mutect2, varscan2
- INPP5D | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64036936; called by muse, mutect2, varscan2
- IRGC | c.613G>C p.A205P | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.473); catalogued as COSV54984109; called by muse, mutect2
- ITGAD | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV54931921; called by muse, mutect2, varscan2
- ITIH6 | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.61); PolyPhen benign (0.038); catalogued as COSV54488979; called by muse, mutect2, varscan2
- ITM2A | c.704-2A>T p.X235_splice | Splice Site (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100964436; called by muse, mutect2, varscan2
- JAM2 | c.338C>A p.A113D | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV57257437; called by muse, mutect2, varscan2
- KALRN | c.2050C>A p.Q684K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.968); catalogued as COSV53763427, COSV53763742; called by muse, mutect2, varscan2
- KCNA3 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV63901566; called by muse, mutect2, varscan2
- KCNA4 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.152); catalogued as COSV60252115; called by muse, mutect2, varscan2
- KCNB1 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.852); catalogued as rs769948178, COSV65568188; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNJ1 | c.63C>G p.F21L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV60661799; called by muse, mutect2, varscan2
- KCNS3 | c.1187T>A p.L396* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as COSV58406741; called by muse, mutect2, varscan2
- KIAA0232 | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV56925304; called by muse, mutect2, varscan2
- KIAA0319L | c.1531C>T p.Q511* | Nonsense Mutation (SNP) | VAF 73/120 reads (61%) | catalogued as COSV100357426, COSV57845619; called by muse, mutect2, varscan2
- KIAA1109 | c.9127C>A p.P3043T | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.254); catalogued as COSV52672461; called by muse, mutect2, varscan2
- KIAA1586 | c.1588A>G p.I530V | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.058); catalogued as COSV66056604; called by muse, mutect2, varscan2
- KIF1B | c.701C>A p.T234N | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV55808535; called by muse, mutect2, varscan2
- KIF2B | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs776230670, COSV52130338; called by muse, mutect2, varscan2
- KIF2B | c.792C>A p.F264L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52130348; called by muse, mutect2, varscan2
- KIF2C | c.1214A>G p.Y405C | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64764483; called by muse, mutect2, varscan2
- KIT | c.1470A>T p.E490D | Missense Mutation (SNP) | VAF 193/243 reads (79%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV55399876; called by muse, mutect2, varscan2
- KIT | c.2478A>C p.K826N | Missense Mutation (SNP) | VAF 30/468 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55399884; called by muse, mutect2
- KLHDC1 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63778783; called by muse, mutect2, varscan2
- KLHL17 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1193417288, COSV100497949; called by mutect2, varscan2
- KLHL32 | c.205-1G>T p.X69_splice | Splice Site (SNP) | VAF 15/66 reads (23%) | catalogued as COSV65111972; called by muse, mutect2
- KRT36 | c.1315G>T p.V439F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as COSV60203371; called by muse, mutect2, varscan2
- KRTAP10-4 | c.1112C>A p.P371H | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV59961676; called by muse, mutect2, varscan2
- LAMA2 | c.4524-1G>T p.X1508_splice | Splice Site (SNP) | VAF 7/27 reads (26%) | catalogued as COSV70346849; called by muse, mutect2, varscan2
- LAMA4 | c.4053G>C p.K1351N (on ENST00000230538 / NM_001105206.3; = p.K1344N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV57896581; called by muse, mutect2, varscan2
- LARP7 | c.877G>T p.G293W | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV100135068; called by muse, mutect2, varscan2
- LATS2 | c.1583C>T p.S528L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs765917652, COSV66875518; called by muse, mutect2, varscan2
- LGALS8 | c.193C>A p.H65N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1345499079, COSV53024565; called by muse, varscan2
- LGALS8 | c.865G>C p.E289Q (on ENST00000341872; = p.E331Q on NM_006499.4) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as rs558536606, COSV53024571; called by muse, mutect2, varscan2
- LILRA2 | c.1074G>T p.E358D | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as rs373320838; called by mutect2, varscan2
- LMLN | c.595G>T p.G199C | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57600756; called by muse, mutect2, varscan2
- LPCAT3 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54645738; called by muse, varscan2
- LPGAT1 | c.854+1G>C p.X285_splice | Splice Site (SNP) | VAF 11/98 reads (11%) | catalogued as COSV65351565; called by muse, mutect2, varscan2
- LRP1B | c.535A>T p.S179C | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV67218182; called by muse, mutect2, varscan2
- LRP2 | c.7304T>A p.F2435Y | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV55552652; called by muse, mutect2, varscan2
- LRP6 | c.2794C>T p.P932S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53787170; called by muse, mutect2
- LRRC4C | c.294C>G p.H98Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.353); catalogued as COSV53425425; called by muse, mutect2, varscan2
- LRRC7 | c.1100T>C p.V367A (on ENST00000651989 / NM_001370785.2; = p.V334A on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV50454915; called by muse, mutect2, varscan2
- LRRIQ1 | c.92G>T p.S31I | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV67813007; called by muse, mutect2, varscan2
- LSAMP | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV61290113; called by muse, mutect2, varscan2
- LSG1 | c.954G>T p.W318C | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV54570129; called by muse, mutect2, varscan2
- LTBP1 | c.2944G>T p.E982* (on ENST00000404816 / NM_206943.4; = p.E656* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 10/87 reads (11%) | catalogued as COSV63186691; called by muse, mutect2, varscan2
- LTBP2 | c.4303G>A p.E1435K | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as COSV56207987; called by muse, mutect2, varscan2
- MACF1 | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 81/127 reads (64%) | catalogued as COSV57102965; called by muse, mutect2, varscan2
- MACF1 | c.21649C>T p.R7217* (on ENST00000372915; = p.R5262* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as COSV57120551; called by muse, mutect2, varscan2
- MAGEB2 | c.26T>A p.L9H | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV66780701; called by muse, mutect2, varscan2
- MAGEB6B | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 43/71 reads (61%) | SIFT tolerated (0.3); PolyPhen benign (0.033); catalogued as COSV101301709; called by muse, mutect2, varscan2
- MAGEC1 | c.2243C>T p.S748F | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as rs1191882102, COSV53572589; called by muse, mutect2, varscan2
- MAGEC3 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 61/86 reads (71%) | SIFT tolerated (0.43); PolyPhen benign (0.065); catalogued as COSV53580095; called by muse, mutect2, varscan2
- MAP1B | c.4365A>T p.Q1455H | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.188); catalogued as rs745772849, COSV57098759; called by muse, mutect2, varscan2
- MAP3K5 | c.3760A>T p.R1254* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as COSV62889126; called by muse, mutect2, varscan2
- MARCHF10 | c.864C>A p.S288R | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV60887107; called by muse, mutect2, varscan2
- MASP1 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs900722298, COSV61826563; called by muse, mutect2, varscan2
- MCEE | c.198G>T p.K66N | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV54905867; called by muse, mutect2, varscan2
- MCOLN3 | c.1349G>T p.C450F | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100352854, COSV62014057; called by muse, mutect2, varscan2
- MCTP1 | c.2644T>C p.Y882H | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.999); catalogued as COSV56514903; called by muse, mutect2, varscan2
- MDN1 | c.2054C>G p.S685C | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65521433; called by muse, varscan2
- MDN1 | c.1984C>T p.Q662* | Nonsense Mutation (SNP) | VAF 44/151 reads (29%) | catalogued as COSV65521442; called by muse, varscan2
- MEIS2 | c.1121A>T p.Q374L (on ENST00000561208 / NM_170675.5; = p.Q354L on NM_002399.3) | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV54935575; called by muse, mutect2, varscan2
- MEIS2 | c.222G>T p.K74N (on ENST00000561208 / NM_170675.5; = p.K61N on NM_002399.3) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54935599; called by muse, mutect2, varscan2
- MEPE | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63072780; called by muse, mutect2, varscan2
- MIER2 | c.658T>C p.Y220H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53395684; called by muse, mutect2, varscan2
- MINAR1 | c.2101A>T p.K701* | Nonsense Mutation (SNP) | VAF 53/141 reads (38%) | catalogued as COSV59582948; called by muse, mutect2, varscan2
- MMEL1 | c.1208T>A p.L403Q | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV56521414; called by muse, mutect2
- MOG | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV65321141; called by muse, mutect2, varscan2
- MOSPD3 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 96/240 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as COSV56158195; called by muse, mutect2, varscan2
- MRGPRX3 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as COSV66933698; called by muse, mutect2, varscan2
- MROH2B | c.857G>A p.R286K | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV68183939; called by muse, mutect2, varscan2
- MRPL16 | c.572G>C p.S191T | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.487); catalogued as COSV55697742; called by muse, mutect2, varscan2
- MRPL30 | c.357C>G p.I119M | Missense Mutation (SNP) | VAF 89/242 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV57666905; called by muse, mutect2, varscan2
- MRPL32 | c.354G>T p.Q118H | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV56239425; called by muse, mutect2, varscan2
- MSI2 | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52358089; called by muse, mutect2, varscan2
- MTCL1 | c.3967G>A p.E1323K (on ENST00000306329 / NM_001378206.1; = p.E1004K on NM_015210.4) | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.508); catalogued as COSV60405985; called by muse, mutect2
- MTX2 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs769302710, COSV50887584, COSV50888039; called by muse, mutect2, varscan2
- MUC16 | c.17976G>T p.E5992D | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.329); catalogued as COSV67464995, COSV67480518; called by muse, mutect2, varscan2
- MUC16 | c.8341G>C p.E2781Q | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV67465001, COSV67495383; called by muse, mutect2, varscan2
- MUC5B | c.3790G>A p.E1264K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV71592012, COSV71596186; called by mutect2, varscan2
- MXRA5 | c.2417A>C p.K806T | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV54234771; called by muse, mutect2, varscan2
- MYCBP2 | c.6344A>T p.E2115V (on ENST00000357337; = p.E2153V on NM_015057.5) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV62018507; called by muse, mutect2, varscan2
- MYEF2 | c.423+1del p.X141_splice | Splice Site (DEL) | VAF 12/45 reads (27%) | catalogued as COSV51047348; called by mutect2, pindel, varscan2
- MYH1 | c.5228G>A p.G1743E | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as rs1451396390, COSV56848243; called by muse, mutect2, varscan2
- MYH1 | c.3389G>C p.R1130P | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56848254; called by muse, mutect2, varscan2
- MYH4 | c.3050A>T p.E1017V | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV55118004; called by muse, mutect2, varscan2
- MYH6 | c.431G>C p.G144A | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV62447612; called by muse, mutect2, varscan2
- MYH6 | c.237G>C p.Q79H | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV62450303; called by muse, mutect2, varscan2
- MYH8 | c.4891C>A p.Q1631K | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV67964875; called by muse, mutect2, varscan2
- MYH8 | c.3750G>T p.K1250N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV67964879; called by muse, mutect2, varscan2
- MYH9 | c.3597G>T p.E1199D | Missense Mutation (SNP) | VAF 104/158 reads (66%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV53386008; called by muse, mutect2, varscan2
- MYH9 | c.3210G>T p.Q1070H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs1201940713, COSV53386018; called by muse, mutect2, varscan2
- MYO10 | c.3853G>T p.D1285Y | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV57021386; called by muse, mutect2, varscan2
- MYPN | c.3581G>A p.R1194H | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1252035616, COSV62733850; called by muse, mutect2
- MYT1L | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV67719846; called by muse, mutect2
- NARS2 | c.109C>G p.Q37E | Missense Mutation (SNP) | VAF 121/203 reads (60%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as rs745404493, COSV55251645; called by muse, mutect2, varscan2
- NBPF10 | c.1182G>C p.L394F | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100744517; called by muse, mutect2, varscan2
- NCKAP5L | c.3736T>A p.S1246T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV60129499; called by muse, mutect2, varscan2
- NEB | c.17606A>G p.K5869R | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV51382029; called by muse, mutect2
- NEGR1 | c.456A>T p.E152D | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV60844395; called by muse, mutect2, varscan2
- NEK10 | c.2091C>T p.C697= | Splice Region (SNP) | VAF 18/34 reads (53%) | catalogued as COSV55358502; called by muse, mutect2, varscan2
- NETO2 | c.1291G>T p.A431S | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.03); catalogued as COSV57452773, COSV57454155; called by muse, mutect2, varscan2
- NF1 | c.7815G>T p.L2605F (on ENST00000358273 / NM_001042492.3; = p.L2584F on NM_000267.3) | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62202937; called by muse, mutect2, varscan2
- NF2 | c.260C>G p.S87* | Nonsense Mutation (SNP) | VAF 37/55 reads (67%) | catalogued as COSV58523753, COSV58525347; called by muse, mutect2, varscan2
- NIN | c.4813G>T p.E1605* (on ENST00000382041 / NM_182946.1; = p.E892* on NM_016350.4) | Nonsense Mutation (SNP) | VAF 21/132 reads (16%) | catalogued as COSV55389821; called by muse, mutect2, varscan2
- NINL | c.3170A>C p.D1057A | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as COSV54002383; called by muse, mutect2, varscan2
- NLRP14 | c.114G>T p.M38I | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.037); catalogued as COSV55067015, COSV55072330; called by muse, mutect2, varscan2
- NLRP14 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as COSV55067026; called by muse, mutect2, varscan2
- NOMO1 | c.3629C>T p.A1210V | Missense Mutation (SNP) | VAF 76/296 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV55058366; called by muse, mutect2, varscan2
- NOTCH2 | c.1475A>G p.E492G | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV56691096; called by muse, mutect2, varscan2
- NPAS2 | c.1366G>T p.G456W | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV59557652; called by muse, mutect2, varscan2
- NRXN1 | c.3221G>T p.G1074V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV58446227, COSV58451619; called by muse, mutect2, varscan2
- NUAK1 | c.1978C>G p.L660V | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54603183; called by muse, mutect2
- NUDT1 | c.74G>C p.G25A (on ENST00000397048 / NM_198952.1; = p.G2A on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV54248080; called by mutect2, varscan2
- NUP153 | c.2392G>T p.E798* | Nonsense Mutation (SNP) | VAF 58/140 reads (41%) | catalogued as COSV50449420; called by muse, mutect2, varscan2
- NUP214 | c.3013G>C p.D1005H | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV63909505; called by muse, mutect2, varscan2
- ODF4 | c.181C>A p.R61S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV60272108; called by muse, mutect2, varscan2
- OLFM3 | c.1054G>A p.D352N (on ENST00000338858 / NM_001288821.1; = p.D332N on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV58798728; called by muse, mutect2, varscan2
- OLFML2B | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs749805939, COSV54196334; called by muse, mutect2, varscan2
- OR10G7 | c.226del p.V76Cfs*5 | Frame Shift Del (DEL) | VAF 15/138 reads (11%) | catalogued as COSV57865581; called by mutect2, pindel, varscan2
- OR10G9 | c.101T>A p.V34E | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV66686242; called by muse, mutect2, varscan2
- OR10Z1 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as rs921532818, COSV63524803; called by muse, mutect2, varscan2
- OR11A1 | c.406C>A p.L136M | Missense Mutation (SNP) | VAF 54/70 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV65820964; called by muse, mutect2, varscan2
- OR13A1 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65572354, COSV65573278; called by muse, mutect2, varscan2
- OR1C1 | c.844G>C p.A282P | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV68715667, COSV68715729; called by muse, mutect2, varscan2
- OR2D3 | c.630C>A p.S210R | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV53492969; called by muse, mutect2, varscan2
- OR2G6 | c.163C>G p.L55V | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58574369; called by muse, varscan2
- OR2T10 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57896714; called by muse, mutect2, varscan2
- OR2T10 | c.481C>A p.P161T | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV57896851; called by muse, mutect2
- OR2T11 | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV58185766; called by muse, mutect2, varscan2
- OR2T3 | c.935C>A p.S312* | Nonsense Mutation (SNP) | VAF 38/370 reads (10%) | catalogued as COSV62082430; called by muse, mutect2, varscan2
- OR2T4 | c.853G>T p.G285W | Missense Mutation (SNP) | VAF 114/207 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63543979, COSV63544827; called by muse, mutect2, varscan2
- OR4C6 | c.614G>T p.C205F | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV58603922, COSV58605715; called by muse, mutect2, varscan2
- OR4D9 | c.253C>A p.L85I | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV61434652; called by muse, mutect2, varscan2
- OR4K15 | c.782G>T p.R261L (on ENST00000305051; = p.R237L on NM_001005486.1) | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59301367, COSV59302267; called by muse, mutect2, varscan2
- OR4N2 | c.633T>A p.F211L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV60051405; called by muse, mutect2, varscan2
- OR51S1 | c.613T>C p.Y205H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59058341; called by muse, mutect2, varscan2
- OR51S1 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs538018962, COSV59057539; called by mutect2, varscan2
- OR52A5 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as rs1301742962, COSV100263360; called by muse, mutect2, varscan2
- OR5AR1 | c.170C>G p.T57R | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV57253755; called by muse, mutect2, varscan2
- OR5B12 | c.160C>G p.H54D | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV56904964; called by muse, mutect2, varscan2
- OR5D18 | c.156C>G p.I52M | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.094); catalogued as COSV61736824, COSV61737091; called by muse, mutect2, varscan2
- OR5J2 | c.624G>T p.M208I | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV56621172; called by muse, mutect2, varscan2
- OR5V1 | c.478A>G p.T160A | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65827864; called by muse, mutect2, varscan2
- OR6F1 | c.697G>T p.G233C | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57467774; called by muse, mutect2, varscan2
- OR6M1 | c.172T>A p.Y58N | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV58433525, COSV58434623; called by muse, mutect2, varscan2
- OR6N2 | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59411379; called by muse, mutect2, varscan2
- OR6T1 | c.230T>A p.V77E | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV58306157, COSV58306850; called by muse, mutect2, varscan2
- OR6V1 | c.699G>T p.Q233H | Missense Mutation (SNP) | VAF 65/112 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs1562993741, COSV69237222; called by muse, mutect2, varscan2
- OR8G5 | c.610G>T p.G204* | Nonsense Mutation (SNP) | VAF 40/94 reads (43%) | catalogued as COSV100422343; called by muse, mutect2, varscan2
- OR8G5 | c.901C>A p.L301M | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.22); catalogued as rs780308830, COSV100422345; called by muse, varscan2
- OR8I2 | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV56167898; called by muse, mutect2, varscan2
- OR8K3 | c.784_785insG p.K262Rfs*7 | Frame Shift Ins (INS) | VAF 7/42 reads (17%) | catalogued as COSV100449731; called by mutect2, pindel, varscan2
- OTOP1 | c.1028G>T p.S343I | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV56393114; called by muse, mutect2, varscan2
- PACRG | c.319C>A p.H107N | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV100432905, COSV61304703, COSV61306447; called by muse, mutect2, varscan2
- PADI1 | c.640T>G p.F214V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64938346; called by muse, mutect2, varscan2
- PAFAH1B1 | c.4G>T p.V2L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.055); catalogued as COSV68211382; called by muse, mutect2, varscan2
- PAM | c.2703A>T p.K901N (on ENST00000438793 / NM_001319943.1; = p.K902N on NM_000919.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV57212937; called by muse, mutect2, varscan2
- PAPOLG | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV53181672; called by muse, mutect2
- PAPPA2 | c.4992G>T p.E1664D | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV62797278; called by muse, mutect2, varscan2
- PARD3 | c.3075G>T p.R1025S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as rs1451404283, COSV61056284; called by muse, varscan2
- PASD1 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 39/53 reads (74%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs750373805, COSV64855229; called by muse, mutect2, varscan2
- PBX1 | c.801G>T p.E267D | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV63343493; called by muse, mutect2, varscan2
- PCCA | c.1050G>C p.M350I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66192171; called by muse, mutect2, varscan2
- PCDH1 | c.3283G>C p.D1095H | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54613842; called by muse, mutect2, varscan2
- PCDH15 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as CM064159, COSV57308507, COSV57355095; called by muse, varscan2
- PCDHA7 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs782545562, COSV65344037; called by muse, mutect2, varscan2
- PCDHB7 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.034); catalogued as COSV50767213; called by muse, mutect2, varscan2
- PCLO | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV61634528; called by muse, mutect2
- PCNT | c.6250A>T p.M2084L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV64027955; called by muse, mutect2, varscan2
- PCNX1 | c.5657A>T p.E1886V | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV53094498; called by muse, mutect2, varscan2
- PCSK5 | c.829G>T p.D277Y | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65088660, COSV65090569; called by muse, mutect2, varscan2
- PDE1C | c.1395G>T p.Q465H | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV58513464, COSV58525821; called by muse, mutect2, varscan2
- PDGFRA | c.2944G>T p.V982L | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT tolerated (0.94); PolyPhen benign (0.01); catalogued as COSV57267920, COSV99955520; called by muse, mutect2
- PDYN | c.484T>A p.Y162N | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV54101727; called by muse, mutect2, varscan2
- PEG3 | c.2459C>A p.A820D | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV55633162, COSV55643610; called by muse, mutect2, varscan2
- PEG3 | c.1716C>G p.F572L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV55623398, COSV55633172; called by muse, mutect2, varscan2
- PGA3 | c.22G>C p.G8R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.761); catalogued as COSV57711672; called by muse, mutect2, varscan2
- PHF14 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 24/51 reads (47%) | catalogued as COSV68855324; called by muse, mutect2, varscan2
- PIK3CG | c.1906T>C p.S636P | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV63248445; called by muse, mutect2, varscan2
- PIK3CG | c.2827G>T p.G943* | Nonsense Mutation (SNP) | VAF 33/100 reads (33%) | catalogued as COSV63248450; called by muse, varscan2
- PIK3CG | c.2828G>T p.G943V | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63248458, COSV63255887; called by muse, mutect2, varscan2
- PIK3R5 | c.2484G>T p.Q828H | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52653708; called by muse, mutect2, varscan2
- PIP4K2A | c.51G>C p.K17N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV64863174; called by muse, mutect2, varscan2
- PKD2 | c.2519A>C p.Q840P | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV52938185, COSV99417260; called by muse, mutect2, varscan2
- PKHD1 | c.5911G>A p.G1971S | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61874814; called by muse, mutect2
- PKP2 | c.2015A>G p.K672R | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV50730592; called by muse, varscan2
- PLAUR | c.473-1G>A p.X158_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as COSV55389733; called by muse, mutect2
- PLCB4 | c.2126C>G p.S709* | Nonsense Mutation (SNP) | VAF 17/30 reads (57%) | catalogued as COSV53801373; called by muse, mutect2, varscan2
- PLEKHG1 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as COSV62047404; called by muse, mutect2, varscan2
- PLEKHG7 | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs749423311, COSV101188841, COSV101188874; called by mutect2, varscan2
- PLPP4 | c.243G>T p.K81N | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV64827878; called by muse, mutect2, varscan2
- PLPP6 | c.883C>G p.R295G | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV56305159; called by muse, mutect2, varscan2
- PLRG1 | c.1172C>G p.S391C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV57423513; called by muse, mutect2, varscan2
- PLXNA1 | c.5179G>C p.D1727H | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV52525981, COSV52534578; called by muse, mutect2, varscan2
- PLXNA4 | c.2870C>T p.S957L | Missense Mutation (SNP) | VAF 91/158 reads (58%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs1264323157, COSV100326997, COSV58124858; called by muse, mutect2, varscan2
- PMS2 | c.1346A>G p.Q449R | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV56221581; called by muse, mutect2, varscan2
- PMS2 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as rs375507981, COSV56150639; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNLIPRP3 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT tolerated (0.99); PolyPhen benign (0.012); catalogued as rs772010729, COSV65047949; called by muse, mutect2, varscan2
- PNMA3 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 36/56 reads (64%) | catalogued as COSV64722308; called by muse, mutect2, varscan2
- POLQ | c.1571G>C p.G524A | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV51751605; called by muse, mutect2, varscan2
- POU6F2 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.17); catalogued as COSV68873327, COSV68882851; called by muse, mutect2, varscan2
- PPP1R9A | c.2958G>T p.Q986H | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV56892210; called by muse, mutect2, varscan2
- PRAMEF10 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.435); catalogued as rs752349251, COSV99338824; called by muse, mutect2, varscan2
- PRH2 | c.49C>A p.Q17K | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.092); catalogued as COSV67171656; called by muse, mutect2, varscan2
- PRKD1 | c.1564A>T p.S522C | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV59568419; called by muse, mutect2, varscan2
- PROZ | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as rs759057455, COSV61439134; called by muse, mutect2, varscan2
- PRPS1L1 | c.818A>T p.N273I | Missense Mutation (SNP) | VAF 42/199 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72649890; called by muse, mutect2, varscan2
- PRR23B | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); catalogued as COSV61493829; called by muse, mutect2, varscan2
- PRUNE2 | c.4192G>T p.E1398* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as COSV65041409; called by muse, mutect2, varscan2
- PSKH2 | c.853-2A>T p.X285_splice | Splice Site (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99405090; called by muse, mutect2, varscan2
- PTAFR | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.281); catalogued as rs184182216, COSV59536809; called by muse, mutect2, varscan2
- PTCHD4 | c.2060G>C p.W687S | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV59779255, COSV59783878; called by muse, mutect2
- PTCHD4 | c.1069C>A p.P357T | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV59783889; called by muse, mutect2, varscan2
- PTH1R | c.1684G>A p.G562R | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.386); catalogued as rs749330849, COSV57315653; called by muse, mutect2, varscan2
- PTHLH | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 94/195 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV52367684; called by muse, mutect2, varscan2
- PTPRN2 | c.2418+1G>A p.X806_splice | Splice Site (SNP) | VAF 11/43 reads (26%) | catalogued as rs994917366, COSV67037027; called by muse, mutect2, varscan2
- PTPRR | c.1246G>C p.G416R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51731810; called by muse, mutect2, varscan2
- PTPRT | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61980543; called by muse, mutect2, varscan2
- QSER1 | c.3167G>T p.S1056I (on ENST00000399302; = p.S1185I on NM_001076786.3) | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs368031810, COSV67900517; called by muse, mutect2, varscan2
- RABGGTA | c.1536G>T p.E512D | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as COSV52863097; called by muse, mutect2, varscan2
- RAG1 | c.750G>T p.K250N | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.033); catalogued as COSV55025211; called by muse, mutect2, varscan2
- RBM12 | c.311G>T p.R104I | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58291239; called by muse, mutect2, varscan2
- REP15 | c.226C>A p.L76M | Missense Mutation (SNP) | VAF 54/96 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV57289850, COSV57291480; called by muse, mutect2, varscan2
- RESF1 | c.3248A>T p.Q1083L | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV57021962; called by muse, mutect2
- REST | c.3215G>A p.G1072E | Missense Mutation (SNP) | VAF 56/89 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58360609; called by muse, mutect2, varscan2
- RIT2 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 328/412 reads (80%) | SIFT tolerated (0.19); PolyPhen benign (0.071); catalogued as COSV56299508; called by muse, varscan2
- RNF213 | c.10049A>G p.Q3350R | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); catalogued as COSV60397188; called by muse, mutect2, varscan2
- ROBO4 | c.2603C>A p.P868H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV100127457; called by mutect2, varscan2
- RPL7A | c.395G>C p.R132T | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as COSV59298251; called by muse, mutect2, varscan2
- RREB1 | c.3748C>T p.H1250Y | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs950151509, COSV58557819; called by muse, mutect2, varscan2
- RSBN1 | c.2214G>T p.R738S | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV54732370; called by muse, varscan2
- RSPH4A | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57634597; called by muse, mutect2, varscan2
- RTN1 | c.2229G>C p.Q743H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50723843, COSV50724983; called by muse, mutect2, varscan2
- RYR2 | c.1518C>G p.H506Q | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV63684929; called by muse, mutect2, varscan2
- RYR2 | c.1658G>T p.G553V | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.958); catalogued as COSV63675528, COSV63684932; called by muse, mutect2, varscan2
- RYR2 | c.13220G>C p.S4407T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV63684948; called by muse, mutect2
- RYR2 | c.14559T>G p.F4853L | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV63684956; called by muse, mutect2, varscan2
- RYR3 | c.6279C>A p.C2093* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV66788553; called by muse, mutect2, varscan2
- RYR3 | c.9101C>A p.S3034Y (on ENST00000389232; = p.S3035Y on NM_001036.6) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV66788562; called by muse, mutect2, varscan2
- RYR3 | c.12928G>T p.E4310* (on ENST00000389232; = p.E4311* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as COSV66788568; called by muse, mutect2, varscan2
- SAFB2 | c.158A>T p.K53M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1295395163, COSV52651336; called by muse, mutect2, varscan2
- SAR1A | c.325G>T p.V109L | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs773757432, COSV64698038; called by muse, mutect2, varscan2
- SARS2 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.194); catalogued as rs773784805, COSV55499538; called by mutect2, varscan2
- SAXO1 | c.643C>G p.P215A | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV65870037; called by muse, mutect2, varscan2
- SBF2 | c.3386G>T p.S1129I | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV56298724; called by muse, mutect2, varscan2
- SCN10A | c.2374A>G p.I792V | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as rs563110484, COSV71861304; called by muse, mutect2, varscan2
- SCN11A | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV56569951; called by muse, mutect2, varscan2
- SCN4A | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.279); catalogued as rs374529559, COSV71126821; called by muse, mutect2, varscan2
- SDCCAG8 | c.1064C>A p.T355N | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs199524638, COSV59409028; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINA4 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV54069235, COSV54069849; called by muse, mutect2, varscan2
- SERPINB12 | c.330C>G p.Y110* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV54033103; called by muse, mutect2, varscan2
- SERPINB4 | c.1043C>G p.A348G | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61984906; called by muse, mutect2, varscan2
- SERPINB4 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs200350590, COSV100346018, COSV61984604; called by muse, mutect2, varscan2
- SERPINB7 | c.171G>T p.L57F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV60533837, COSV60535798; called by muse, mutect2, varscan2
- SERPINC1 | c.459C>G p.F153L | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.763); catalogued as COSV62929363, COSV62929393; called by muse, mutect2, varscan2
- SEZ6 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV57979776; called by muse, mutect2, varscan2
- SH3RF3 | c.1509G>C p.K503N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58685960, COSV58695199; called by muse, mutect2, varscan2
- SHKBP1 | c.141-1G>T p.X47_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | catalogued as COSV52539783; called by muse, mutect2, varscan2
- SHOX | c.16G>C p.A6P | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV61860814; called by muse, mutect2, varscan2
- SI | c.4829C>A p.P1610H | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773851366, COSV52277886; called by mutect2, varscan2
- SIDT1 | c.1721-1G>C p.X574_splice | Splice Site (SNP) | VAF 38/113 reads (34%) | catalogued as COSV53499938, COSV53501052; called by muse, mutect2, varscan2
- SIM1 | c.1907G>C p.R636T | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.165); catalogued as COSV53492002; called by muse, mutect2, varscan2
- SLC16A11 | c.372C>A p.F124L (on ENST00000308009; = p.F100L on NM_153357.3) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.926); catalogued as COSV57274217, COSV57274824; called by muse, mutect2, varscan2
- SLC1A6 | c.841G>C p.V281L | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV55670318; called by muse, mutect2, varscan2
- SLC25A12 | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as rs1376678275, COSV55533382; called by muse, mutect2, varscan2
- SLC25A15 | c.430G>C p.G144R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV58557047; called by muse, mutect2, varscan2
- SLC27A2 | c.437G>A p.C146Y | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51058945; called by muse, mutect2, varscan2
- SLC35F3 | c.104G>T p.S35I | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.043); catalogued as COSV64026398; called by muse, mutect2, varscan2
- SLC36A4 | c.1369G>T p.A457S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV58396139; called by muse, mutect2, varscan2
- SLC38A1 | c.1152G>C p.K384N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as COSV67063490; called by muse, varscan2
- SLC4A10 | c.1494G>T p.W498C (on ENST00000446997 / NM_001354461.2; = p.W468C on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs781388732, COSV55777903; called by muse, varscan2
- SLC4A8 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 33/113 reads (29%) | catalogued as COSV60651966; called by muse, mutect2, varscan2
- SLC4A8 | c.668A>C p.Q223P | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV60652004; called by muse, mutect2, varscan2
- SLC5A7 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV50891458; called by muse, mutect2, varscan2
- SLC5A7 | c.1178C>A p.T393K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV50891479; called by muse, mutect2, varscan2
- SLC6A11 | c.477C>A p.S159R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV54393448; called by muse, mutect2, varscan2
- SLC9C2 | c.1853T>G p.L618W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV62945739; called by muse, mutect2, varscan2
- SLFN12 | c.1594A>T p.K532* | Nonsense Mutation (SNP) | VAF 32/56 reads (57%) | catalogued as COSV59225873; called by muse, mutect2, varscan2
- SNAPC4 | c.561G>A p.W187* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as COSV53733117; called by muse, mutect2, varscan2
- SNX13 | c.383C>G p.S128C | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV68064999; called by muse, mutect2, varscan2
- SON | c.2723C>T p.S908L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV51657235; called by muse, mutect2, varscan2
- SORL1 | c.4814C>T p.T1605I | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV52754327; called by muse, mutect2, varscan2
- SORL1 | c.5491C>G p.L1831V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV52754337; called by muse, mutect2, varscan2
- SOS2 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV53567505; called by muse, mutect2, varscan2
- SP4 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 21/50 reads (42%) | catalogued as COSV56022660, COSV99754194; called by muse, mutect2, varscan2
- SPAM1 | c.648G>T p.W216C | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56143562; called by muse, mutect2, varscan2
- SPANXN2 | c.189A>G p.I63M | Missense Mutation (SNP) | VAF 69/104 reads (66%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as COSV65128321; called by muse, varscan2
- SPATA31D1 | c.1957C>G p.P653A | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.708); catalogued as COSV61195629; called by muse, mutect2, varscan2
- SPIC | c.3+1G>T p.X1_splice | Splice Site (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100162912; called by muse, mutect2, varscan2
- SPTA1 | c.6067G>C p.A2023P | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.114); catalogued as COSV63752847; called by muse, mutect2, varscan2
- SPTA1 | c.3952G>T p.A1318S | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63752853, COSV63756067; called by muse, mutect2, varscan2
- SPTA1 | c.2977C>A p.P993T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.151); catalogued as COSV63752856, COSV63759518; called by muse, mutect2, varscan2
- SRD5A1 | c.323G>C p.G108A | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV57013887; called by muse, mutect2, varscan2
- SRD5A1 | c.714-2A>T p.X238_splice | Splice Site (SNP) | VAF 21/69 reads (30%) | catalogued as rs1389730511, COSV57013894; called by muse, mutect2, varscan2
- SRGN | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54344807; called by mutect2, varscan2
- SRPRB | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71749081; called by muse, mutect2, varscan2
- SSH2 | c.2245G>T p.V749F | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99281782; called by muse, mutect2, varscan2
- SST | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 86/307 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs201328656, COSV55030709, COSV55031390; called by muse, mutect2, varscan2
- ST8SIA6 | c.465G>T p.E155D | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV66468223; called by muse, mutect2, varscan2
- STAC | c.37G>T p.D13Y | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.823); catalogued as COSV56210477; called by muse, varscan2
- STBD1 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV52953799; called by muse, mutect2, varscan2
- STPG1 | c.368A>G p.K123R (on ENST00000337248 / NM_001199013.2; = p.K76R on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV50219212; called by muse, mutect2, varscan2
- STPG2 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 36/64 reads (56%) | catalogued as COSV54797420; called by muse, mutect2, varscan2
- SUCO | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.1); catalogued as rs1271277493, COSV55263593, COSV55265161; called by muse, mutect2, varscan2
- SULF1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs776280066, COSV52680986; called by muse, mutect2, varscan2
- SULF1 | c.2207G>A p.G736E | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.424); catalogued as COSV52680995; called by muse, mutect2, varscan2
- SYTL2 | c.568C>G p.Q190E | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.155); catalogued as COSV60358969; called by muse, mutect2
- TARBP1 | c.2507G>T p.G836V | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.198); catalogued as COSV50184148; called by muse, mutect2, varscan2
- TAS2R1 | c.349T>A p.W117R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66778510; called by muse, mutect2, varscan2
- TAS2R41 | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV68765231; called by muse, mutect2, varscan2
- TBK1 | c.177G>T p.L59F | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100538437, COSV59155109; called by muse, mutect2, varscan2
- TBX18 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63736792; called by muse, mutect2, varscan2
- TBX3 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57471477; called by muse, mutect2, varscan2
- TDRD1 | c.3303G>T p.E1101D | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.461); catalogued as COSV52590583; called by muse, mutect2, varscan2
- TDRD10 | c.470G>T p.R157M | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV100873047; called by muse, mutect2, varscan2
- TDRD9 | c.1573G>C p.E525Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV59146942; called by muse, mutect2
- TFAM | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs138243284; called by muse, mutect2, varscan2
- TFAP2D | c.82G>T p.G28C | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99145828; called by muse, mutect2, varscan2
- TG | c.2429G>C p.R810T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV55075748; called by muse, mutect2, varscan2
- TG | c.2764C>A p.P922T | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV55075762, COSV99603850; called by mutect2, varscan2
- TG | c.7754G>T p.R2585L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs146323019, COSV99600089; called by mutect2, varscan2
- TLL1 | c.2891G>C p.R964P | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50274369, COSV50278762; called by muse, mutect2, varscan2
- TM9SF2 | c.334-2A>T p.X112_splice | Splice Site (SNP) | VAF 3/23 reads (13%) | catalogued as COSV64506733; called by muse, mutect2
- TMBIM6 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 68/160 reads (43%) | catalogued as COSV57279525; called by muse, mutect2, varscan2
- TMC3 | c.2785G>A p.A929T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as rs915456777, COSV63923115; called by muse, mutect2, varscan2
- TMEM102 | c.555C>G p.D185E | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV53439684; called by muse, mutect2, varscan2
- TMEM108 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.075); catalogued as COSV100419573, COSV58871533; called by muse, mutect2, varscan2
- TMEM109 | c.31G>T p.G11* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as COSV50005625; called by muse, mutect2, varscan2
- TMEM132B | c.2676G>C p.R892S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54753404; called by muse, mutect2, varscan2
- TMEM14C | c.35G>A p.W12* | Nonsense Mutation (SNP) | VAF 48/128 reads (38%) | catalogued as rs781579263, COSV57638288; called by muse, mutect2, varscan2
- TMEM45A | c.681G>T p.W227C | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV60253434; called by muse, mutect2, varscan2
- TMEM71 | c.610A>T p.S204C (on ENST00000523829 / NM_001382398.1; = p.S185C on NM_144649.3) | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as COSV63457324; called by muse, mutect2, varscan2
- TNFAIP8 | c.176G>T p.R59M | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs1562038398, COSV57227088; called by muse, mutect2, varscan2
- TNN | c.1209C>A p.D403E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.03); catalogued as rs1056031201, COSV99511621; called by muse, mutect2, varscan2
- TNR | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54885090; called by muse, mutect2, varscan2
- TNRC6A | c.2597G>T p.W866L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.994); catalogued as COSV59364164; called by muse, mutect2, varscan2
- TP53 | c.619del p.D207Mfs*40 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | catalogued as COSV52839530; called by mutect2, pindel, varscan2
- TRA2A | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs766465878, COSV51716836; called by muse, mutect2, varscan2
- TRAF6 | c.1242G>A p.M414I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61922454; called by muse, mutect2, varscan2
- TRBJ2-7 | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as rs1390654673; called by muse, mutect2, varscan2
- TRBV3-1 | c.124T>A p.C42S | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773173340; called by muse, mutect2, varscan2
- TRDN | c.115G>T p.D39Y | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100522573, COSV62121453; called by muse, mutect2, varscan2
- TRIM7 | c.1145C>A p.T382N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51242371; called by muse, mutect2, varscan2
- TRIOBP | c.4501G>A p.E1501K | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.026); catalogued as COSV60377272; called by muse, mutect2, varscan2
- TRIOBP | c.4654G>C p.E1552Q | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV60377282; called by muse, mutect2, varscan2
- TRIOBP | c.4903G>A p.E1635K | Missense Mutation (SNP) | VAF 35/51 reads (69%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs956428499, COSV100730848, COSV60377289; called by muse, mutect2, varscan2
- TRMT10C | c.283A>T p.R95* | Nonsense Mutation (SNP) | VAF 24/94 reads (26%) | catalogued as COSV59305811; called by muse, mutect2, varscan2
- TRPC1 | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.287); catalogued as COSV56425149; called by muse, mutect2, varscan2
- TRPC4 | c.2188G>T p.G730C (on ENST00000379705 / NM_016179.4; = p.G735C on NM_003306.3) | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58999704; called by muse, mutect2, varscan2
- TRPM4 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99419459; called by muse, varscan2
- TRPM6 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV62506425, COSV62509830; called by muse, mutect2, varscan2
- TRPV2 | c.235C>A p.L79I | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.489); catalogued as COSV58428224; called by muse, mutect2, varscan2
- TSHZ1 | c.1475G>T p.G492V (on ENST00000580243 / NM_001308210.2; = p.G447V on NM_005786.6) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.086); catalogued as COSV59009270; called by muse, mutect2, varscan2
- TSHZ3 | c.2734G>T p.A912S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs759742847, COSV53663538, COSV53671227; called by muse, mutect2, varscan2
- TTLL4 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.04); catalogued as COSV51436376; called by muse, mutect2, varscan2
- TTN | c.88511T>A p.I29504N (on ENST00000591111; = p.I22080N on NM_003319.4) | Missense Mutation (SNP) | VAF 53/223 reads (24%) | PolyPhen possibly damaging (0.885); catalogued as COSV60050179; called by muse, mutect2, varscan2
- TTN | c.62942C>A p.T20981K (on ENST00000591111; = p.T13557K on NM_003319.4) | Missense Mutation (SNP) | VAF 41/131 reads (31%) | PolyPhen probably damaging (0.923); catalogued as COSV60050219; called by muse, mutect2, varscan2
- TTN | c.58357G>T p.A19453S (on ENST00000591111; = p.A12029S on NM_003319.4) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | PolyPhen benign (0.027); catalogued as COSV60050264; called by muse, mutect2, varscan2
- TTN | c.52825C>T p.Q17609* (on ENST00000591111; = p.Q10185* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as COSV60050339; called by muse, mutect2, varscan2
- TTN | c.45974T>A p.V15325D (on ENST00000591111; = p.V7901D on NM_003319.4) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | PolyPhen probably damaging (0.998); catalogued as COSV60050373; called by muse, mutect2, varscan2
- TTN | c.42823G>A p.E14275K (on ENST00000591111; = p.E6851K on NM_003319.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | PolyPhen benign (0); catalogued as COSV60050409; called by muse, mutect2
- TTN | c.27254G>T p.R9085L (on ENST00000591111; = p.R8158L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/113 reads (30%) | PolyPhen benign (0.022); catalogued as COSV60050448, COSV60086820; called by muse, mutect2, varscan2
- TXK | c.97A>T p.S33C | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV51914888; called by muse, mutect2, varscan2
- UBD | c.120G>C p.K40N | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV63542459; called by muse, mutect2, varscan2
- UGT1A7 | c.538G>T p.G180C | Missense Mutation (SNP) | VAF 78/149 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV60832874, COSV60838872; called by muse, mutect2, varscan2
- UGT2B11 | c.1329G>T p.M443I | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV101485291, COSV71423354; called by muse, mutect2, varscan2
- UGT2B28 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV59431959; called by muse, mutect2, varscan2
- UNC5B | c.684G>C p.K228N | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV58977098, COSV58979657; called by muse, mutect2, varscan2
- UNC79 | c.2571G>T p.E857D (on ENST00000393151 / NM_001346218.2; = p.E680D on NM_020818.5) | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.979); catalogued as COSV56387360; called by muse, mutect2, varscan2
- USH2A | c.14321G>A p.S4774N | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV56367688; called by muse, mutect2
- USH2A | c.11899G>C p.D3967H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV56367700; called by muse, mutect2, varscan2
- USH2A | c.9461C>G p.A3154G | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV56367712; called by muse, mutect2, varscan2
- USH2A | c.8464C>G p.Q2822E | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV56367723; called by muse, varscan2
- USH2A | c.8381T>A p.V2794D | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56367741; called by muse, varscan2
- USH2A | c.328A>G p.T110A | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV56367783; called by muse, varscan2
- USP20 | c.482A>C p.Q161P | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59613799; called by muse, mutect2, varscan2
- UTRN | c.4628C>A p.S1543* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as COSV62335141; called by muse, mutect2, varscan2
- VAT1L | c.858G>T p.K286N | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56819911; called by muse, mutect2, varscan2
- VIRMA | c.1630G>C p.V544L | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV52584918; called by muse, mutect2
- VN1R5 | c.111C>G p.I37M | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as rs1429481468; called by muse, mutect2, varscan2
- VPS13B | c.1149G>C p.L383F | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.289); catalogued as COSV62019305; called by muse, mutect2, varscan2
- VWF | c.2922G>T p.W974C | Missense Mutation (SNP) | VAF 117/174 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54619930; called by muse, varscan2
- WARS1 | c.1101G>T p.Q367H | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV59925335; called by muse, varscan2
- WARS1 | c.1058G>T p.S353I | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59925517; called by muse, varscan2
- WEE2 | c.1536-2A>C p.X512_splice | Splice Site (SNP) | VAF 17/103 reads (17%) | catalogued as COSV66878865; called by muse, mutect2, varscan2
- WT1 | c.730T>C p.F244L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.079); catalogued as COSV60071455; called by muse, mutect2, varscan2
- XIRP2 | c.3371C>T p.T1124I (on ENST00000628543; = p.T1299I on NM_152381.6) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV54699363; called by muse, mutect2, varscan2
- XIRP2 | c.8108A>G p.E2703G (on ENST00000628543; = p.E2878G on NM_152381.6) | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as COSV54699382; called by muse, mutect2
- XIRP2 | c.8110A>T p.S2704C (on ENST00000628543; = p.S2879C on NM_152381.6) | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.87); catalogued as COSV54699395; called by muse, mutect2
- XKR4 | c.1870G>C p.E624Q | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.575); catalogued as rs200999097, COSV59314601; called by muse, mutect2, varscan2
- XYLT1 | c.2734G>T p.G912W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV54484156; called by muse, mutect2, varscan2
- YIPF3 | c.925G>T p.G309C | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58304697; called by muse, mutect2, varscan2
- ZBTB22 | c.659C>A p.S220Y | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.248); catalogued as COSV56468359, COSV56469212; called by muse, mutect2, varscan2
- ZC3H11A | c.301G>T p.V101L | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV59746306; called by muse, mutect2, varscan2
- ZC3H18 | c.1899-1G>C p.X633_splice | Splice Site (SNP) | VAF 7/17 reads (41%) | catalogued as COSV56324562; called by muse, mutect2, varscan2
- ZC4H2 | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.619); catalogued as COSV62003355, COSV62003567; called by muse, mutect2, varscan2
- ZFHX4 | c.7798G>A p.E2600K | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as rs756270586, COSV50780927; called by muse, mutect2, varscan2
- ZFP42 | c.703C>A p.H235N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58817359; called by mutect2, varscan2
- ZFP64 | c.673C>T p.H225Y | Missense Mutation (SNP) | VAF 70/141 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53798993; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1993G>T p.E665* | Nonsense Mutation (SNP) | VAF 44/91 reads (48%) | catalogued as COSV58742778; called by muse, mutect2, varscan2
- ZNF215 | c.1531C>A p.L511M | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.708); catalogued as rs768103509, COSV53492988; called by muse, varscan2
- ZNF236 | c.2563C>T p.Q855* | Nonsense Mutation (SNP) | VAF 15/90 reads (17%) | catalogued as COSV53488072; called by muse, mutect2, varscan2
- ZNF236 | c.2564A>T p.Q855L | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV53488093; called by muse, mutect2, varscan2
- ZNF236 | c.3352G>T p.E1118* | Nonsense Mutation (SNP) | VAF 11/84 reads (13%) | catalogued as COSV53488116; called by muse, mutect2, varscan2
- ZNF25 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV56922544; called by muse, mutect2
- ZNF33A | c.462G>T p.L154F (on ENST00000458705 / NM_006974.3; = p.L155F on NM_006954.2) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.963); catalogued as COSV56724912; called by muse, mutect2, varscan2
- ZNF33B | c.1417G>T p.E473* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as COSV63942527, COSV63943211; called by muse, mutect2, varscan2
- ZNF41 | c.1496A>C p.E499A | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV57442545; called by muse, mutect2, varscan2
- ZNF48 | c.798G>T p.Q266H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100198075; called by muse, varscan2
- ZNF530 | c.1489G>A p.G497R | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60531522; called by muse, mutect2, varscan2
- ZNF536 | c.3682G>T p.A1228S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.01); catalogued as rs563418287, COSV62823921; called by muse, mutect2, varscan2
- ZNF804A | c.2891C>A p.S964* | Nonsense Mutation (SNP) | VAF 21/85 reads (25%) | catalogued as COSV56447970; called by muse, mutect2, varscan2
- ZNRF4 | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV55774110; called by muse, mutect2, varscan2
- ZSCAN5B | c.932C>A p.P311H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.87); catalogued as COSV61999934; called by muse, mutect2, varscan2
- ALDH3A1 | c.916G>T p.G306W | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ALDH3A1 | c.915T>A p.Y305* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | called by mutect2, varscan2
- BCAS2 | c.94-25_94-2del p.X32_splice | Splice Site (DEL) | VAF 34/153 reads (22%) | called by mutect2, pindel
- GAS2L2 | c.2311A>T p.I771F | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- IGHV3-16 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGHV3-43 | c.309C>A p.N103K | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- IGLV2-33 | c.251C>G p.S84* | Nonsense Mutation (SNP) | VAF 74/287 reads (26%) | called by muse, mutect2, varscan2
- ITGA1 | c.274dup p.C92Lfs*9 | Frame Shift Ins (INS) | VAF 18/48 reads (38%) | called by mutect2, pindel, varscan2
- LSM5 | c.218del p.L73Cfs*2 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, varscan2
- MEAF6 | c.567+2dup | Splice Region (INS) | VAF 27/78 reads (35%) | called by mutect2, pindel, varscan2
- MKI67 | c.4895_4904del p.R1632Hfs*8 | Frame Shift Del (DEL) | VAF 32/146 reads (22%) | called by pindel, varscan2
- OR2T8 | c.715T>G p.C239G | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- OR8G2P | c.800C>A p.S267Y | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- OTX2 | c.95del p.P32Rfs*19 (on ENST00000408990 / NM_172337.3; = p.P32Rfs*27 on NM_021728.4) | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- POLR2G | c.369del p.N124Tfs*13 | Frame Shift Del (DEL) | VAF 22/127 reads (17%) | called by mutect2, pindel, varscan2
- RBM28 | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RBP3 | c.1257G>C p.E419D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- RBP3 | c.1431C>G p.D477E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEC24A | c.1670_1679del p.G557Efs*9 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | called by mutect2, pindel, varscan2
- SLC22A3 | c.1596del p.E533Kfs*39 | Frame Shift Del (DEL) | VAF 14/75 reads (19%) | called by mutect2, pindel, varscan2
- SLITRK1 | c.858del p.P287Qfs*39 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- ST8SIA6 | c.578dup p.I194Nfs*4 | Frame Shift Ins (INS) | VAF 19/65 reads (29%) | called by mutect2, pindel, varscan2
- TENM2 | c.3088_3094del p.I1030Sfs*36 (on ENST00000518659 / NM_001122679.2; = p.I798Sfs*36 on NM_001080428.3) | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- THBS2 | c.2748del p.F916Lfs*85 | Frame Shift Del (DEL) | VAF 14/75 reads (19%) | called by mutect2, pindel, varscan2
- TPTE | c.1360C>A p.L454I (on ENST00000618007 / NM_199261.4; = p.L436I on NM_199259.4) | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TRDV3 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- TRRAP | c.935del p.G312Efs*21 | Frame Shift Del (DEL) | VAF 20/112 reads (18%) | called by mutect2, pindel, varscan2
- TSPEAR | c.1696_1698del p.Y566del | In Frame Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- TUBB4B | c.1172del p.R391Pfs*25 | Frame Shift Del (DEL) | VAF 42/158 reads (27%) | called by mutect2, pindel*, varscan2
- XAGE2 | c.82-1G>C p.X28_splice | Splice Site (SNP) | VAF 44/78 reads (56%) | called by muse, mutect2, varscan2
- ZBBX | c.1898del p.P633Lfs*57 | Frame Shift Del (DEL) | VAF 32/123 reads (26%) | called by mutect2, pindel, varscan2
- ZBTB24 | c.414_416del p.T139del | In Frame Del (DEL) | VAF 43/139 reads (31%) | called by pindel, varscan2
- ABCA3 | c.603C>A p.G201= | Silent (SNP) | VAF 123/241 reads (51%) | catalogued as COSV57053456; called by muse, mutect2, varscan2
- ABCA7 | c.4455C>G p.A1485= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV54029242; called by muse, mutect2, varscan2
- ABCA9 | c.4155G>T p.V1385= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV60624672; called by muse, mutect2, varscan2
- ABCB5 | c.3327G>A p.E1109= (on ENST00000404938 / NM_001163941.2; = p.E664= on NM_178559.6) | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV51705599, COSV51709393; called by muse, mutect2, varscan2
- ACTN2 | c.393G>T p.L131= | Silent (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2
- ACY3 | c.396C>T p.H132= | Silent (SNP) | VAF 48/84 reads (57%) | catalogued as rs774216129, COSV54828785; called by muse, mutect2, varscan2
- ADAD1 | c.1068C>G p.L356= | Silent (SNP) | VAF 54/86 reads (63%) | catalogued as COSV56643370; called by muse, mutect2, varscan2
- ADAL | c.675G>A p.L225= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV67500503; called by muse, mutect2, varscan2
- ADAMTS14 | c.2037C>G p.V679= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV64601962; called by muse, mutect2, varscan2
- ADAMTS3 | c.60T>A p.A20= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as COSV54391160; called by muse, mutect2, varscan2
- AGTPBP1 | c.2754G>T p.R918= (on ENST00000357081 / NM_001330701.2; = p.R878= on NM_015239.2) | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV61271513; called by muse, mutect2, varscan2
- ARRDC5 | c.24C>A p.L8= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV101108116, COSV101108133; called by mutect2, varscan2
- ASPM | c.684C>T p.F228= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV54129651; called by muse, mutect2, varscan2
- ASPN | c.1083T>C p.P361= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV65016111; called by muse, mutect2, varscan2
- ATG2B | c.882G>A p.L294= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV63423102; called by muse, mutect2, varscan2
- ATG7 | c.1068C>G p.V356= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as COSV61612391; called by muse, mutect2, varscan2
- ATRNL1 | c.894C>A p.P298= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV61803919; called by muse, mutect2, varscan2
- BEGAIN | c.297C>G p.L99= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV62068711; called by muse, mutect2, varscan2
- BMPER | c.963C>A p.I321= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV51818141; called by muse, mutect2, varscan2
- BMPER | c.1869T>C p.N623= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs1273778197, COSV51818154; called by muse, mutect2
267 further variants in this file (0 protein-altering or splice-affecting, 244 silent, 23 other) are not listed here.
